Surgical pathology report (de-identified scan), TCGA case TCGA-MJ-A850, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-MJ-A850-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Received:

PATHOLOGIC DIAGNOSIS

A. LYMPH NODE, RIGHT NECK LEVEL 2, EXCISION:

- NO MALIGNANCY SEEN IN TWO IDENTIFIED LYMPH NODES (0/2)

B. PHARYNX, RIGHT PHARYNGEAL SUPERIOR MARGIN, EXCISION:

- NO MALIGNANCY IDENTIFIED

C. SOFT TISSUE, RIGHT INFERIOR CONSTRUCTOR MARGIN, EXCISION:

- NO MALIGNANCY IDENTIFIED

D. PRE EPIGLOTTIC FISSURE, EXCISION:

- NO MALIGNANCY IDENTIFIED

E. RIGHT LATERAL ARYTENOID, BIOPSY:

- NO MALIGNANCY IDENTIFIED

F. RIGHT CRICOTHYROID MUSCULATURE, BIOPSY:

- NO MALIGNANCY IDENTIFIED

H. RIGHT NECK, LEVEL 3, REGIONAL DISSECTION:

- THIRTEEN LYMPH NODES IDENTIFIED; ALL NEGATIVE FOR MALIGNANCY (0/13)

I. RIGHT NECK, LEVEL 2A, REGIONAL DISSECTION:

- SIX LYMPH NODES IDENTIFIED, ALL NEGATIVE FOR MALIGNANCY

J. RIGHT PHARYNX, PHARYNGECTOMY:

- SYNOVIAL SARCOMA, MONOPHASIC PATTERN

- DIFFERENTIATION SCORE 3/3, MITOTIC SCORE 3/3, NECROSIS SCORE 1/2

(LESS THAN 50%), CUMULATIVE SCORE = 7; CORRESPONDS TO "FNCLCC GRADE 3"

K. RIGHT SUBMANDIBULAR GLAND, EXCISION:

- NO MALIGNANCY IDENTIFIED

ICD O-3
Sarcoma, synovial monophasic
fibrous
9041/3
Site: Soft tissue, head, face & neck
C49.0
Pharynx C14.0
11/29/13

Staff Pathologist

Intraoperative Consultation

Intraoperative Frozen Section Diagnosis:

Lymph nodes, right neck level II, biopsy;

[page 2 of 4]
- Two lymph nodes identified, as follows:
- FSA1-TPA1: One lymph node, negative for carcinoma (0/1)
- TPA2: One lymph node, negative for carcinoma (0/1)
- Reported to _____ in _____ at _____ by _____
- FSB: Right pharyngeal superior margin, biopsy: marked negative for malignancy.
- FSC: Right inferior constrictor margin, biopsy: marked negative for malignancy.
- FSD: Pre Epiglottic fissure, biopsy: marked negative for malignancy.
- FSE: Right lateral arytenoid biopsy: marked negative for malignancy.
- FSF: Right cricothyroid musculature, biopsy: marked negative for malignancy. FSG: Right arytenoid margin, biopsy: marked negative for malignancy.

Staff Pathologist

Pathology Resident

Pertinent Clinical Information

Right neck sarcoma.

Gross Description

Specimen Material: A. Right neck level II lymph node, B. Right pharyngeal superior margin, C. Right inferior constrictor margin, soft tissue, D. Epiglottic cartilage pre fissure, E. Right lateral arytenoid cartilage, F. Right cricothyroid musculature, G. Right margin arytenoid cartilage. H. Neck, dissection R side level III: I. Neck, R dissection level IIA: J. Pharynx, R pharyngectomy: K. Submandibular gland, R:

Part A: Received fresh for intraoperative consultation labeled "RIGHT NECK LEVEL II LYMPH NODE" and consists of two tan-pink lymph nodes within fatty adipose tissue. The largest lymph node is 1.8 x 1.2 x 0.5 cm, the second lymph node is 1 x 0.7 x 0.5 cm. The lymph nodes are severally sectioned; the largest lymph node is tan-pink with a slight central pale discoloration. The smaller lymph node is bi-valved, cut surface is homogenous tan-pink. Touch preps are made. The largest lymph node is submitted entirely for frozen section analysis in cassettes FSA1. The remaining lymph node is entirely submitted in A2.

Part B: Received fresh labeled "RIGHT PHARYNGEAL SUPERIOR MARGIN" is a 0.8 x 0.8 x 0.3 cm portion of tan-red tissue. One surface is cauterized, and the opposite surface is not. The cauterized surface is inked purple and specimen is submitted en face in a single cassette FSB.

Part C: Received fresh labeled "RIGHT INFERIOR CONSTRICTOR MARGIN" is a 2 x 0.8 x 0.5 cm portion of brown-red tissue. One surface is

[page 3 of 4]
cauterized, and the opposite surface is not. The cauterized surface is inked purple and the specimen is submitted en face in a single cassette C.

Part D: Received fresh labeled "PRE EPIGLOTTIC FISSURE" is a 1.2 x 0.5 x 0.3 cm portion of tan-red tissue. One side of the tissue is cauterized, and the opposite side is not. The cauterized side is inked purple, and the specimen is submitted en face in a single cassette C.

Part E: Received fresh labeled "RIGHT LATERAL ARYTENOID" is a 1.1 x 0.9 x 0.2 cm portion of maroon-red tissue. One surface of the tissue is cauterized, and the opposite side is not. The specimen is inked blue and submitted en face and in toto in a single cassette E.

Part F: Received fresh labeled "RIGHT CRICOTHYROID MUSCULATURE" is a 1.2 x 1.2 x 0.3 cm portion of tan-red tissue. One surface of the tissue is cauterized, and the opposite side is not. The cauterized surface is inked orange, and the specimen is submitted in toto en face in a single cassette F.

Part G: Received in formalin labeled "RIGHT ARYTENOID MARGIN" is a 0.9 x 0.5 x 0.3 cm portion of tan-red tissue. One surface of the tissue is cauterized, and the opposite side is not. The cauterized surface is inked red, and the specimen is submitted in toto, en face in a single cassette G.

Part H. Received in formalin labeled "NECK DISSECTION RIGHT SIDE LEVEL III," is an unoriented regular portion of fibrofatty tissue measuring 4 x 3 x 0.5 cm. Vascular and muscular tissue is not identified. Multiple possible lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 cm to 0.9 x 0.6 x 0.6 cm. The lymph nodes are submitted in toto in cassettes H1 four possible whole nodes, cassette H2 five possible whole nodes, cassette H3 four possible whole nodes.

Part I. Received in formalin labeled "RIGHT NECK DISSECTION LEVEL IIA," are three irregular pieces of fibrofatty tissue aggregating to 2.5 x 2.2 x 0.8 cm. Within the fibrofatty tissue, four possible whole nodes are identified ranging from 0.7 x 0.7 x 0.6 cm to 3 x 0.8 x 0.2 cm. The specimen is submitted in toto in cassettes I1 three possible whole nodes, cassette I2 is one possible whole node.

Part J. Received in formalin labeled "RIGHT PHARYNGECTOMY," is a partial pharyngectomy consisting of thyroid partial right strap muscles, portion of the right thyroid cartilage, pharyngeal mucosa and a mass measuring approximately 3.5 x 3.5 cm. The specimen measures 10 cm from superior to inferior, 6 cm from left to right and 5.5 cm from anterior posterior. The portion of thyroid cartilage measures 4.8 x 2.5 x 0.2 cm. The mass has 1.6

[page 4 of 4]
x 1 cm ulceration through the tan-pink mucosa. The mass is located 1.6 cm from the thyroid cartilage, 0.2 cm from the pyriformis, 1.5 cm from the right thyroid lobe and approximately 0.5 cm from the attached straps muscle. The specimen is inked and serially sectioned to reveal the mass to be 5 x 3.5 x 2.6 cm. The mass is a tan-white homogenous cut surface it is located 0.2 cm from the superior aspect abuts the blue ink anteriorly, and 0.2 cm from the nearest right (purple) margin. The mass extends inferiorly and over the thyroid cartilage 0.7 cm, but not appear to involve the cartilage. The thyroid lobe and anterior strap muscles are entirely uninvolved.

Serial sectioning to the thyroid reveals a tan parenchyma with no lesions.

Ink code:

Red superior

Blue anterior

Black posterior

Violet right

Representative sections are submitted as follows:

J1. Superior aspect submitted en face

J2. Mass to nearest anterior (blue) margin

J3 to J4. Mass to nearest right (purple) margin

J5. Mass to thyroid cartilage

J6-J8. Representative mass

J9. Representative thyroid

J10. Representative anterior strap muscles.

Part K. Received in formalin labeled "RIGHT SUBMANDIBULAR GLAND RIGHT SUBMANDIBULAR GLAND," is a 10.3 gram, 4.3 x 3 x 0.6 cm tan-pink lobulated gland. The ducts are identified. The cut surface displays golden-yellow glandular tissue within interspersed fibrous septae. There are no calculi or masses identified. Representative sections are submitted in K1-K3.

Pathology Assistant

Pathology Resident

Microscopic Description

A-K: Performed.

The staff pathologist listed below has reviewed this case.

****Electronically Signed Out****

Source: NCI Genomic Data Commons file 29ae772c-e1a6-441c-94c6-8562c8e04403 (TCGA-MJ-A850.16C71B81-171B-499A-83E8-27CB6BB6A23C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).